HCMI case HCM-BROD-0419-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0ee7109-8e30-4789-b071-cd80bec493a3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 603 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 72.4 years (26,453 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -9 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 20 days; Days to treatment end: 64 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 30 days; Days to treatment end: 262 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 478 days (1.3 years); Karnofsky performance status: 70.
- Days to follow up: 603 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- IDH1 (IHC): Positive; Amino-acid change: R132H.
- MGMT methylation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 160 cm; BMI: 21.9.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0419-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0419-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 7.
